TARGET case TARGET-30-PAIFCS — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9b850179-9d18-51f9-a121-105deef6252c

Demographics
Sex at birth: male; Race: white; Age at index: 4 years; Vital status: Dead; Days to death: 919 days (2.5 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C80.0; Classification of tumor: primary; Age at diagnosis: 4.2 years (1,540 days); Year of diagnosis: 1995; Days to last follow up: 919 days (2.5 years); Cog neuroblastoma risk group: High Risk; INSS stage: Stage 4.
   Pathology details: Necrosis percent: 5; Percent tumor nuclei: 95.
   Treatment given: Protocol identifier: 9047.
   Treatment given: Protocol identifier: 9341.
   Treatment given: Protocol identifier: 9340.

Follow-up (2 entries)
- Days to follow up: 200 days; Days to first event: 200 days; First event: Event.
- Days to follow up: 919 days (2.5 years); Year of follow up: 1998.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Normal; Ploidy: Diploid.

Biospecimens (2 samples)
- Sample TARGET-30-PAIFCS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAIFCS-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- First Event: Event
- Overall Survival Time in Days: 919
- Protocol: 9047, 9340, 9341
- Ploidy: Diploid (DI=1)
- Ploidy Value: 1
- Histology: Unfavorable
- Percent Necrosis: 5
- Percent Tumor v/s Stroma: 75/25
